HCMI case HCM-EXPT-1069-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/b2765761-9c40-4b33-ab6b-e3154e34c644

Demographics
Sex at birth: male; Year of birth: 1945.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.0; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 72.9 years (26,623 days); Prior treatment: Yes.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Neoadjuvant.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-1069-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-1069-C18-01A-01-S1-HE: Section location: Top; Percent tumor cells: 29; Percent tumor nuclei: 40; Percent normal cells: 43; Percent necrosis: 1; Percent stromal cells: 27; Percent lymphocyte infiltration: 9; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-1069-C18-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 19; Percent tumor nuclei: 25; Percent normal cells: 57; Percent necrosis: 1; Percent stromal cells: 23; Percent lymphocyte infiltration: 18; Percent monocyte infiltration: 7; Percent neutrophil infiltration: 0.
